Gene-level copy-number profile of tumor specimen ALCH-B2QN-TTP1-A from ALCHEMIST case ALCH-B2QN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.0 years (26,286 days).
Specimen ALCH-B2QN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ca762137-9ac3-4bfb-a71d-e014605eb30d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2QN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/5afcd86b-48cb-4219-a46c-c3628caad5cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 9,063; copy number 2: 46,016; copy number 3: 3,817; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr19:58,012,589–58,025,926, 2 genes: VN2R19P, AC008969.2.
- chr20:38,419,638–38,435,409, 6 genes: SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,361,820–18,391,105, 2 genes, copy number 5: FAM230J, AC011718.1.
- chr22:18,527,157–18,530,573, 2 genes, copy number 5: AC023490.3, TMEM191B.

Autosomal genes at a single copy (total copy number 1): 6,208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
